Gene-level copy-number profile of tumor specimen TCGA-HU-A4H5-01A from TCGA case TCGA-HU-A4H5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 71.8 years (26,232 days).
Specimen TCGA-HU-A4H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f9465824-7f99-4ae6-a245-ec6d6fc82a38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4H5-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/22fbd8de-ed0f-494a-9e88-d7f334a7d135

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 1,287; copy number 2: 17,616; copy number 3: 15,021; copy number 4: 18,901; copy number 5: 4,352; copy number 6: 1,312; copy number 7: 635; copy number 8: 266; copy number 9: 282; copy number 10: 6; copy number 12: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4H5-01A-21D-A253-01): tumor purity 0.64, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,154,869–181,238,604, 21 genes: QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732, AL358393.1, LINC01699.
- chr4:145,444,899–145,469,638, 2 genes: AC093796.1, NMNAT1P4.
- chr4:145,497,073–145,502,971, 1 gene: SMAD1-AS2.
- chr7:70,972–260,772, 10 genes: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1.
- chr9:14,040,716–15,362,134, 23 genes: RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33.
- chr12:113,583,886–113,773,726, 1 gene (within-gene range 0–2): LINC01234.
- chr21:37,365,477–38,661,780, 17 genes (within-gene range 0–2): AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1.
- chr22:41,367,333–41,446,801, 4 genes: TEF, RNU6-495P, AL008582.1, TOB2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 338 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,651,706–178,921,841, 6 genes, copy number 10 (within-gene range 1–10): AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63.
- chr20:40,685,848–55,075,140, 332 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
